Somatic mutation profile of tumor specimen TCGA-44-2655-01A (aliquot TCGA-44-2655-01A-01D-1553-08) from TCGA case TCGA-44-2655, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.3 years (23,854 days).
Specimen TCGA-44-2655-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15b7e9b4-d91b-4922-8716-823254743be6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2655-11A (Solid Tissue Normal), aliquot TCGA-44-2655-11A-01D-1553-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c34b137-098b-4e76-9ed1-52e1be916fd0

The open-access MAF lists 196 somatic variants for this specimen: 142 protein-altering or splice-affecting, 49 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 49, Nonsense Mutation 7, Splice Site 4, Frame Shift Del 4, Intron 3, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.3774G>C p.K1258N (on ENST00000265723 / NM_018849.3; = p.K1251N on NM_000443.4) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV55939226; called by muse, mutect2, varscan2
- ACTL7B | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65927824; called by muse, mutect2, varscan2
- ADAM30 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV65561703; called by muse, mutect2, varscan2
- ALDH5A1 | c.592G>C p.A198P | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62373625, COSV62374251; called by muse, mutect2, varscan2
- ANAPC11 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58712171; called by muse, mutect2
- ANKEF1 | c.1376A>G p.Y459C | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs201360021, COSV65693064; called by muse, mutect2, varscan2
- ANKRD55 | c.919T>A p.Y307N | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as COSV61946096, COSV61948970; called by muse, mutect2, varscan2
- ANKRD55 | c.579A>T p.K193N | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV61948977; called by muse, mutect2, varscan2
- ANKS1B | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs866244804, COSV100245739, COSV61365156; called by muse, mutect2, varscan2
- ARPP21 | c.2213C>A p.P738H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51803819, COSV51808046; called by muse, mutect2, varscan2
- ASPM | c.10144A>T p.T3382S | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.191); catalogued as rs759672320, COSV54134820; called by muse, mutect2
- BRINP3 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.049); catalogued as COSV66533854; called by muse, mutect2, varscan2
- BRWD3 | c.1697G>T p.R566L | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100956252, COSV64751757; called by muse, mutect2
- C11orf68 | c.277G>T p.V93L (on ENST00000530188; = p.V134L on NM_031450.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as COSV56989227; called by muse, mutect2
- C1orf94 | c.1652C>A p.S551Y (on ENST00000488417 / NM_001134734.2; = p.S361Y on NM_032884.5) | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV64914836; called by muse, mutect2, varscan2
- CACNA2D1 | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV62387125; called by muse, varscan2
- CD1D | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63808990, COSV63809555; called by muse, mutect2, varscan2
- CHRNB4 | c.757G>T p.V253F | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55715653, COSV55717328; called by muse, varscan2
- CNTRL | c.4561G>T p.E1521* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | catalogued as COSV53050833; called by muse, mutect2, varscan2
- COL22A1 | c.2140-1G>T p.X714_splice | Splice Site (SNP) | VAF 25/153 reads (16%) | catalogued as COSV57350309; called by muse, mutect2, varscan2
- COL24A1 | c.1921C>A p.R641S | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV65310470; called by muse, mutect2
- CSF1R | c.1344G>T p.Q448H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.505); catalogued as COSV53839789; called by muse, mutect2, varscan2
- CSN2 | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV61992440; called by muse, mutect2, varscan2
- CYSLTR2 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56166555; called by muse, mutect2
- DCAF12L2 | c.1289C>G p.A430G | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV63580722, COSV63582449, COSV63583358; called by muse, mutect2, varscan2
- DDX11 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV52508287; called by muse, mutect2
- DISP3 | c.998G>T p.C333F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53822673; called by muse, mutect2
- DLGAP2 | c.1678G>T p.D560Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70095249, COSV70101970; called by muse, mutect2
- DNAH9 | c.6647T>A p.I2216N | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as COSV52365398; called by muse, mutect2, varscan2
- DRC1 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV56533756; called by muse, mutect2
- DZIP1 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV61268147; called by muse, mutect2, varscan2
- EXT1 | c.2188_2189insC p.K730Tfs*15 | Frame Shift Ins (INS) | VAF 8/90 reads (9%) | catalogued as COSV100984136; called by mutect2, pindel
- FAT4 | c.2640C>A p.N880K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV67894860; called by muse, mutect2, varscan2
- FCRL1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV63826531; called by muse, mutect2, varscan2
- FLNB | c.3788G>T p.G1263V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1017971561, COSV55888644; called by muse, mutect2, varscan2
- FLRT2 | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58147011; called by mutect2, varscan2
- FMN2 | c.2705T>G p.L902R | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV60443597; called by muse, mutect2, varscan2
- FOXP3 | c.1121T>A p.F374Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM086634, COSV66051770; called by muse, mutect2, varscan2
- FUBP1 | c.838-1G>T p.X280_splice | Splice Site (SNP) | VAF 9/77 reads (12%) | catalogued as COSV53935486; called by muse, mutect2, varscan2
- GABRR1 | c.814T>A p.Y272N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV65620097; called by muse, mutect2
- GALNT13 | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.213); catalogued as COSV67231577; called by muse, mutect2, varscan2
- GLIPR2 | c.326G>T p.W109L | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV65029507; called by muse, mutect2, varscan2
- HDGFL3 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV55207709; called by muse, mutect2, varscan2
- HHATL | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV55136301; called by muse, mutect2, varscan2
- IFNGR1 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62992471; called by muse, mutect2
- IL16 | c.2347C>A p.P783T (on ENST00000302987 / NM_172217.5; = p.P82T on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100267696, COSV100268148; called by muse, mutect2
- IL16 | c.2348C>A p.P783H (on ENST00000302987 / NM_172217.5; = p.P82H on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100268155; called by muse, mutect2
- INHBC | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV59005790; called by muse, mutect2, varscan2
- IPO7 | c.2918A>G p.N973S | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV65686270; called by muse, mutect2, varscan2
- JADE3 | c.2154G>T p.E718D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); catalogued as COSV54468713; called by muse, mutect2, varscan2
- KCNA2 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs941480281, COSV60368715, COSV60370638; called by muse, mutect2
- KEAP1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV50562178, COSV50635540; called by muse, mutect2, varscan2
- KIAA1210 | c.4541G>T p.R1514M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV68178774; called by muse, mutect2, varscan2
- LAMP5 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as COSV55717401; called by muse, mutect2, varscan2
- LCN2 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as COSV52979936; called by muse, mutect2, varscan2
- LPA | c.2984T>C p.V995A | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as COSV60306848; called by muse, mutect2, varscan2
- LTBP1 | c.2552T>A p.V851D (on ENST00000404816 / NM_206943.4; = p.V525D on NM_000627.4) | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63194133; called by muse, mutect2, varscan2
- MAGEE1 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV63909797, COSV63911389; called by muse, mutect2, varscan2
- MC5R | c.699C>A p.S233R | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.82); catalogued as COSV61255272; called by muse, mutect2, varscan2
- MECOM | c.2442T>A p.N814K (on ENST00000468789 / NM_001105078.4; = p.N1002K on NM_004991.4) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV52970302; called by muse, mutect2, varscan2
- MINAR1 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV59585116; called by muse, mutect2, varscan2
- MKRN3 | c.637C>G p.R213G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.532); catalogued as CD136255, COSV58811244; called by mutect2, varscan2
- MUC16 | c.34925C>A p.T11642N | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV67481267; called by muse, mutect2, varscan2
- MUC16 | c.25831C>A p.P8611T | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.158); catalogued as COSV67481268; called by muse, mutect2, varscan2
- NALCN | c.3049A>T p.I1017F | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51920545; called by muse, mutect2
- NEK11 | c.963-2A>T p.X321_splice | Splice Site (SNP) | VAF 71/477 reads (15%) | catalogued as COSV63582704; called by muse, mutect2, varscan2
- NETO1 | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55011745; called by muse, mutect2, varscan2
- NIT1 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100919087; called by muse, mutect2, varscan2
- NIT1 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100919139; called by muse, mutect2, varscan2
- NLRP8 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV52591386; called by muse, mutect2, varscan2
- NOMO1 | c.3370G>T p.D1124Y | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV55060347; called by mutect2, varscan2
- NOTCH4 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV66682763; called by muse, mutect2
- NRCAM | c.3307G>T p.A1103S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV61044158; called by muse, mutect2, varscan2
- NYNRIN | c.4333G>T p.A1445S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66843932; called by muse, mutect2, varscan2
- OR10W1 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV67720716; called by muse, mutect2, varscan2
- OR12D2 | c.514A>C p.I172L | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV65829397; called by muse, mutect2
- OR2T2 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 57/379 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.783); catalogued as COSV61618454, COSV61618659; called by muse, mutect2, varscan2
- OR2T6 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.592); catalogued as COSV63216840; called by muse, mutect2, varscan2
- OR2T6 | c.500C>A p.P167Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63216841; called by muse, mutect2, varscan2
- OR52N2 | c.76C>A p.H26N | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1000151819, COSV57677453; called by muse, mutect2, varscan2
- OR5AP2 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs751028738, COSV57258220; called by muse, mutect2, varscan2
- OR6F1 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as COSV100129000, COSV57468794; called by muse, mutect2, varscan2
- OR6K6 | c.143C>A p.A48E (on ENST00000368144; = p.A24E on NM_001005184.1) | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV63743582, COSV63744609; called by muse, mutect2, varscan2
- PAFAH1B2 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV59167314; called by muse, mutect2, varscan2
- PAK5 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.186); catalogued as rs758725931, COSV62033816; called by muse, mutect2
- PAPLN | c.1721A>G p.Q574R (on ENST00000554301; = p.Q547R on NM_173462.4) | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.236); catalogued as COSV53721447; called by muse, mutect2
- PCBP2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs111807426, COSV63729469; called by muse, mutect2, varscan2
- PCDH11X | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53442685, COSV53490194; called by muse, mutect2, varscan2
- PCDHB6 | c.1854C>A p.H618Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV50711920, COSV99171417; called by muse, mutect2, varscan2
- PCDHGA2 | c.1094T>C p.I365T | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as rs776665790, COSV53997740; called by muse, mutect2, varscan2
- PDE7A | c.1190G>T p.G397V (on ENST00000401827 / NM_001242318.3; = p.G371V on NM_002603.4) | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV65154046; called by muse, mutect2
- PFKFB1 | c.1158G>T p.E386D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | PolyPhen benign (0.007); catalogued as COSV66628030; called by muse, mutect2
- PHACTR3 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.927); catalogued as COSV100733234, COSV63024900; called by muse, mutect2, varscan2
- PLCB1 | c.3516G>T p.K1172N | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as COSV62061168; called by muse, mutect2, varscan2
- PLXNB1 | c.3449G>T p.R1150L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV56492525; called by muse, mutect2, varscan2
- POF1B | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV53137963; called by muse, mutect2
- PPP1R15B | c.2083A>G p.M695V | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as rs1259963039, COSV65816258; called by muse, mutect2, varscan2
- PRLR | c.494C>A p.T165K | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV51498379, COSV51499567; called by muse, mutect2, varscan2
- PRPF18 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as rs531649538, COSV60725929; called by muse, mutect2, varscan2
- PTPRN2 | c.1882G>T p.G628C | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV67053197; called by muse, mutect2
- RALA | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50048751, COSV50049964; called by muse, mutect2, varscan2
- RBMS2 | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV56265181; called by muse, mutect2, varscan2
- RIPK1 | c.1053G>T p.M351I | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV52530850; called by muse, mutect2, varscan2
- RNF150 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60787394, COSV60796350; called by muse, mutect2, varscan2
- RYR2 | c.8121T>A p.D2707E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV63702112; called by muse, mutect2, varscan2
- S1PR3 | c.1082C>A p.S361* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV63981026; called by muse, mutect2, varscan2
- SACS | c.2524G>T p.D842Y | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV66538285; called by muse, mutect2, varscan2
- SEMA4A | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV100740674, COSV61773495; called by muse, mutect2, varscan2
- SERPINA4 | c.1004G>T p.R335M | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as COSV54071047; called by muse, mutect2, varscan2
- SERPINI2 | c.1108C>A p.P370T | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52987881; called by muse, mutect2
- SEZ6L | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50673879; called by muse, mutect2, varscan2
- SEZ6L | c.2800C>T p.Q934* | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | catalogued as COSV50673911; called by muse, mutect2
- SIPA1L2 | c.3892G>T p.A1298S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs376696486, COSV53395734; called by muse, mutect2, varscan2
- SLC9A9 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57227336; called by muse, mutect2, varscan2
- SMG1 | c.2621C>G p.S874C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV67173729; called by muse, mutect2, varscan2
- SNX18 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100410534; called by muse, mutect2, varscan2
- SOD2 | c.527T>G p.L176R | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61623222; called by muse, mutect2
- SOX6 | c.2213G>T p.G738V (on ENST00000528429 / NM_001145819.2; = p.G711V on NM_017508.3) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57053037; called by muse, mutect2
- STYXL2 | c.2291G>T p.G764V | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV54808110, COSV54810780; called by muse, mutect2, varscan2
- SYNE1 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.282); catalogued as COSV55052229; called by muse, mutect2, varscan2
- TAF4 | c.2719C>T p.Q907* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | catalogued as COSV53341085; called by muse, mutect2, varscan2
- TBX5 | c.857A>T p.N286I | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV59863612; called by muse, mutect2, varscan2
- TNC | c.5350G>A p.G1784S | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV60788217; called by muse, mutect2, varscan2
- TNR | c.3063G>T p.M1021I | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.266); catalogued as COSV54902767; called by muse, mutect2, varscan2
- TRAF3IP2 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV60676693; called by muse, mutect2, varscan2
- TRIM11 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV52856366; called by muse, mutect2, varscan2
- TRPM1 | c.66T>A p.S22R | Missense Mutation (SNP) | VAF 64/579 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV56639017; called by muse, mutect2, varscan2
- TRPV4 | c.2237G>T p.R746L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55684055; called by muse, mutect2, varscan2
- TTC29 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57273436, COSV57281175; called by muse, mutect2, varscan2
- UNC5D | c.2110C>G p.L704V | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV54803166, COSV54818500; called by muse, mutect2, varscan2
- UTP18 | c.1113+1G>T p.X371_splice | Splice Site (SNP) | VAF 7/63 reads (11%) | catalogued as COSV56584628; called by muse, mutect2, varscan2
- VCAM1 | c.164del p.P55Hfs*9 | Frame Shift Del (DEL) | VAF 17/126 reads (13%) | catalogued as COSV54119167; called by mutect2, pindel
- WNT7B | c.699C>G p.N233K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as rs374174469, COSV59751531; called by muse, mutect2, varscan2
- ZFHX4 | c.3317A>T p.N1106I | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV51479822; called by muse, mutect2, varscan2
- ZIC3 | c.650C>G p.P217R | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV54975727; called by muse, mutect2
- ZNF251 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV52958471; called by muse, mutect2, varscan2
- FZD10 | c.1304del p.D435Afs*24 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- IGHG3 | c.1108A>T p.S370C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2
- NOX1 | c.86_90delinsA p.A29Dfs*2 | Frame Shift Del (DEL) | VAF 16/198 reads (8%) | called by pindel, varscan2*
- PCK1 | c.318del p.T108Qfs*27 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- TRAV2 | c.324_326delinsA p.Y108* | Nonsense Mutation (DEL) | VAF 8/95 reads (8%) | called by pindel, varscan2*
- TRPC7 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2
- ADAMTSL3 | c.2139G>T p.G713= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV54439254; called by muse, mutect2
- AHNAK | c.14256C>T p.G4752= | Silent (SNP) | VAF 25/251 reads (10%) | catalogued as rs778265937, COSV57223598; called by muse, mutect2, varscan2
- ANGPTL1 | c.339G>C p.V113= | Silent (SNP) | VAF 11/208 reads (5%) | catalogued as COSV52367519; called by muse, mutect2
- BCOR | c.2502C>T p.S834= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs776803302, COSV60714081; called by muse, mutect2, varscan2
- BEND4 | c.1095G>A p.L365= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV72469278; called by muse, mutect2, varscan2
- BOC | c.1296C>A p.P432= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV56355355; called by muse, mutect2
- CASR | c.1959C>A p.L653= (on ENST00000490131; = p.L730= on NM_000388.4) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV56139757; called by muse, mutect2, varscan2
- CCDC88A | c.1560T>C p.S520= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV55066900; called by muse, mutect2, varscan2
- CFTR | c.2262G>A p.V754= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV50077944; called by muse, mutect2, varscan2
- COL6A6 | c.1518C>A p.I506= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV100649961, COSV62032399; called by muse, mutect2, varscan2
- CRHR2 | c.1227C>T p.A409= | Silent (SNP) | VAF 26/189 reads (14%) | catalogued as rs752866618, COSV59267012; called by muse, mutect2, varscan2
- CTCF | c.1659G>T p.A553= | Silent (SNP) | VAF 25/203 reads (12%) | catalogued as COSV50493226; called by muse, mutect2, varscan2
- CTCF | c.1809C>T p.R603= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV50493412; called by muse, mutect2
- DCDC1 | c.3891G>T p.V1297= (on ENST00000597505 / NM_001367979.1; = p.V404= on NM_020869.3) | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as COSV58001488; called by muse, mutect2, varscan2
- EFCAB6 | c.2136G>A p.Q712= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as COSV53068584, COSV53074462; called by muse, varscan2
- FLOT2 | c.597G>A p.K199= | Silent (SNP) | VAF 21/201 reads (10%) | catalogued as COSV67529303; called by muse, mutect2, varscan2
- FZD3 | c.1155T>A p.V385= | Silent (SNP) | VAF 35/213 reads (16%) | catalogued as COSV53536947; called by muse, mutect2, varscan2
- GK5 | c.954A>G p.P318= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV67486430; called by muse, mutect2, varscan2
- HTR2C | c.1215T>A p.A405= | Silent (SNP) | VAF 30/213 reads (14%) | catalogued as COSV52219675; called by muse, mutect2, varscan2
- IHH | c.447C>T p.R149= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs573679558, COSV55393732; called by muse, mutect2
- IQGAP2 | c.3930G>T p.V1310= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV57178109; called by muse, mutect2, varscan2
- IRAK4 | c.1302T>C p.S434= | Silent (SNP) | VAF 22/220 reads (10%) | catalogued as rs551524673, COSV71210788; called by muse, mutect2, varscan2
- KIF13B | c.738G>T p.V246= | Silent (SNP) | VAF 19/191 reads (10%) | catalogued as COSV73054620; called by muse, mutect2
- KIF9 | c.1200G>A p.R400= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV55522124; called by muse, mutect2, varscan2
- LAIR2 | c.45G>T p.L15= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV56622449; called by muse, mutect2
- LDLRAD3 | c.807G>T p.A269= | Silent (SNP) | VAF 33/260 reads (13%) | catalogued as rs760761455, COSV59678877, COSV59685667; called by muse, mutect2, varscan2
- MUC16 | c.2520C>A p.L840= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as COSV101199000, COSV67481271; called by muse, mutect2, varscan2
- NUP210 | c.741G>T p.P247= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as COSV54410524, COSV54414409; called by muse, mutect2, varscan2
- OR2A5 | c.783C>A p.A261= | Silent (SNP) | VAF 19/167 reads (11%) | catalogued as COSV68738975; called by muse, mutect2, varscan2
- OR4A47 | c.246C>A p.G82= | Silent (SNP) | VAF 30/224 reads (13%) | catalogued as COSV71445082; called by muse, mutect2, varscan2
- PAX1 | c.1533C>A p.P511= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV68272779; called by muse, mutect2
- PHACTR3 | c.684C>A p.L228= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100733232; called by muse, mutect2, varscan2
- PLPPR5 | c.562C>A p.R188= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as rs368223363, COSV54175754; called by muse, mutect2
- RARS2 | c.1293A>T p.A431= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV65762033; called by muse, mutect2, varscan2
- RASA1 | c.2250A>T p.T750= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as COSV57199300; called by muse, mutect2, varscan2
- RYR3 | c.4254C>A p.A1418= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV66802295; called by muse, mutect2, varscan2
- SATL1 | c.699C>A p.G233= (on ENST00000395409; = p.G420= on NM_001012980.2) | Silent (SNP) | VAF 32/264 reads (12%) | catalogued as rs776707377, COSV60575484; called by muse, mutect2
- SCN3A | c.3771C>A p.L1257= | Silent (SNP) | VAF 77/502 reads (15%) | catalogued as COSV51818415; called by muse, mutect2, varscan2
- SCN3B | c.573C>A p.A191= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV54800514; called by muse, mutect2, varscan2
- SERPINA12 | c.555C>A p.T185= | Silent (SNP) | VAF 33/232 reads (14%) | catalogued as COSV57942546, COSV57945061; called by muse, mutect2, varscan2
- SLC20A2 | c.1701G>T p.T567= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV60605515; called by muse, mutect2, varscan2
- SLC36A3 | c.1374C>A p.I458= | Silent (SNP) | VAF 22/272 reads (8%) | catalogued as COSV58857751; called by muse, mutect2
- SNRNP200 | c.3252C>T p.V1084= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV60492776; called by muse, mutect2, varscan2
- TDRD5 | c.573C>A p.T191= | Silent (SNP) | VAF 51/161 reads (32%) | catalogued as COSV54247557; called by muse, mutect2, varscan2
- TMEM132B | c.2046C>A p.I682= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV54756898, COSV54762832; called by muse, mutect2, varscan2
- TNXB | c.4101G>T p.L1367= (on ENST00000647633; = p.L1120= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV64484842, COSV64488576; called by muse, mutect2, varscan2
- ZFHX4 | c.1863G>T p.V621= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV50480848; called by muse, mutect2, varscan2
- ZNF777 | c.84C>T p.P28= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs1241734584, COSV56099280; called by muse, mutect2, varscan2
- ZNF835 | c.144G>T p.G48= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV73379632; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503358 ins GA | 5'Flank (INS) | VAF 10/83 reads (12%) | called by mutect2, pindel, varscan2
- DPP6 | c.627+20964G>T | Intron (SNP) | VAF 16/129 reads (12%) | catalogued as COSV59621180; called by muse, mutect2, varscan2
- MAP3K19 | c.3222+381C>A | Intron (SNP) | VAF 24/163 reads (15%) | catalogued as COSV100209321; called by muse, mutect2, varscan2
- NACA | c.70+3890del | Intron (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- NBPF7 | n.439G>T | RNA (SNP) | VAF 27/215 reads (13%) | called by muse, mutect2, varscan2
